CCDI case PBBPLA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/46d9842d-8474-43b7-9bfe-31a3aeb1999f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 17.7 years (6,468 days).

Biospecimens (3 samples)
- Sample 0DEAYT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEAZ1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEAZ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
